Somatic mutation profile of tumor specimen MMRF_2753_1_BM_CD138pos (aliquot MMRF_2753_1_BM_CD138pos_T1_KHS5U_L15087) from MMRF case MMRF_2753, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.5 years (23,914 days).
Specimen MMRF_2753_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef73ea95-8275-4d9d-a7b1-ee7f3cf7eee4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2753_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2753_1_PB_WBC_C2_KHS5U_L15088; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aadf79dc-9352-48f0-a67d-4eb6317d4cf8

The open-access MAF lists 108 somatic variants for this specimen: 38 protein-altering or splice-affecting, 14 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, 3'UTR 26, Intron 16, Silent 14, 5'UTR 5, Nonsense Mutation 5, 5'Flank 4, RNA 3, Splice Site 3, 3'Flank 2, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C2orf78 | c.2669G>A p.R890H | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs748756915; called by muse, mutect2, varscan2
- COL11A1 | c.1791G>T p.K597N | Missense Mutation (SNP) | VAF 7/187 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as CS1411323; called by muse, mutect2
- CREBBP | c.4617T>A p.Y1539* | Nonsense Mutation (SNP) | VAF 24/78 reads (31%) | catalogued as COSV52128775; called by muse, mutect2, varscan2
- IFI27L1 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV101267237; called by muse, mutect2, varscan2
- IGKV4-1 | c.179C>G p.A60G | Missense Mutation (SNP) | VAF 68/75 reads (91%) | SIFT tolerated (0.3); PolyPhen benign (0.078); catalogued as rs142986022; called by muse, mutect2, varscan2
- KCNA3 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 82/119 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.211); catalogued as COSV63902063; called by muse, mutect2, varscan2
- KCNA6 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99768200; called by muse, mutect2, varscan2
- KIF13A | c.1710T>G p.S570R | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV52456475; called by muse, mutect2, varscan2
- KRAS | c.190T>G p.Y64D | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55534434, COSV55579983, COSV55703886; called by muse, mutect2, varscan2
- LMNB1 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54397408; called by muse, mutect2, varscan2
- NELL1 | c.1738G>A p.G580S | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749886230, COSV100121136; called by muse, mutect2, varscan2
- NOX3 | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs149980019; called by muse, mutect2, varscan2
- RNF20 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as rs1564107221; called by muse, mutect2, varscan2
- SEMA3F | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs755533288, COSV99065574; called by muse, mutect2, varscan2
- SRI | c.52-5C>T | Splice Region (SNP) | VAF 83/175 reads (47%) | catalogued as COSV56000671; called by muse, mutect2, varscan2
- ADCY2 | c.1153G>C p.G385R | Missense Mutation (SNP) | VAF 66/125 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGAP3 | c.844G>A p.A282T (on ENST00000622464; = p.A318T on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- ARID2 | c.170T>G p.L57* | Nonsense Mutation (SNP) | VAF 29/78 reads (37%) | called by muse, mutect2, varscan2
- BZW1 | c.163G>C p.D55H | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CBX6 | c.94T>A p.W32R | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH10 | c.1876+1G>A p.X626_splice | Splice Site (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- CELSR3 | c.9813C>A p.H3271Q | Missense Mutation (SNP) | VAF 75/135 reads (56%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD2 | c.2243_2244dup p.S749Hfs*8 | Frame Shift Ins (INS) | VAF 76/207 reads (37%) | called by pindel, varscan2
- CSDE1 | c.778A>T p.I260F (on ENST00000358528 / NM_001007553.3; = p.I229F on NM_007158.6) | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSG4 | c.1679G>A p.G560E | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- GOLGA4 | c.4618G>A p.E1540K | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GPAA1 | c.1850T>G p.V617G | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- HEXIM1 | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 73/161 reads (45%) | called by muse, mutect2, varscan2
- IGKV1-6 | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- INF2 | c.646C>G p.Q216E | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2
- KRT6C | c.755+1G>C p.X252_splice | Splice Site (SNP) | VAF 40/117 reads (34%) | called by muse, varscan2
- KRTAP10-5 | c.209C>G p.T70R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.075); called by muse, mutect2
- MAF1 | c.626C>G p.S209C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- RILP | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- RNPEPL1 | c.1934_1938del p.A645Efs*49 | Frame Shift Del (DEL) | VAF 45/95 reads (47%) | called by mutect2, pindel, varscan2
- RPS20 | c.177+2T>A p.X59_splice | Splice Site (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- SACS | c.8695G>T p.D2899Y | Missense Mutation (SNP) | VAF 74/84 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SMU1 | c.1328G>A p.G443E | Missense Mutation (SNP) | VAF 97/365 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- CLN8 | c.831C>T p.N277= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs200083273; ClinVar: likely benign; called by muse, mutect2, varscan2
- CSNK1G1 | c.480C>G p.L160= | Silent (SNP) | VAF 131/282 reads (46%) | called by muse, varscan2
- DLC1 | c.2685G>A p.A895= (on ENST00000276297 / NM_001348081.2; = p.A458= on NM_006094.5) | Silent (SNP) | VAF 63/139 reads (45%) | catalogued as rs973811381; called by muse, mutect2, varscan2
- FAM166A | c.231C>T p.P77= | Silent (SNP) | VAF 49/154 reads (32%) | called by muse, mutect2, varscan2
- LLGL2 | c.2445A>C p.S815= | Silent (SNP) | VAF 53/118 reads (45%) | called by muse, mutect2, varscan2
- OPHN1 | c.66C>T p.L22= | Silent (SNP) | VAF 76/81 reads (94%) | called by muse, mutect2, varscan2
- PIWIL4 | c.2463A>G p.A821= | Silent (SNP) | VAF 100/232 reads (43%) | called by muse, mutect2, varscan2
- RUBCN | c.633C>T p.P211= | Silent (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- RUFY2 | c.72G>A p.E24= | Silent (SNP) | VAF 60/118 reads (51%) | called by muse, mutect2, varscan2
- SATB1 | c.1863C>A p.G621= | Silent (SNP) | VAF 45/85 reads (53%) | called by muse, mutect2, varscan2
- SIM1 | c.663C>T p.A221= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV53495966, COSV53497316; called by muse, mutect2, varscan2
- SLC36A3 | c.1065G>A p.P355= | Silent (SNP) | VAF 42/93 reads (45%) | catalogued as rs187566485; called by muse, mutect2, varscan2
- VWDE | c.603G>A p.L201= | Silent (SNP) | VAF 76/175 reads (43%) | catalogued as COSV51728968; called by muse, mutect2, varscan2
- ZSCAN5B | c.711C>T p.S237= | Silent (SNP) | VAF 35/77 reads (45%) | called by muse, mutect2, varscan2
- AC092368.2 | chr16:46569024 G>A | 5'Flank (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- AC105942.1 | n.1137G>A | RNA (SNP) | VAF 8/62 reads (13%) | catalogued as rs71652594; called by muse, mutect2, varscan2
- AC125421.1 | n.325-35G>A | Intron (SNP) | VAF 57/176 reads (32%) | called by muse, mutect2, varscan2
- ALDH7A1 | c.*2163C>T | 3'UTR (SNP) | VAF 58/138 reads (42%) | called by muse, mutect2, varscan2
- AR | c.*1700A>G | 3'UTR (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021477 del AACCGGTGCC | 5'Flank (DEL) | VAF 70/182 reads (38%) | called by mutect2, pindel, varscan2
- BRI3BP | c.*158G>A | 3'UTR (SNP) | VAF 46/88 reads (52%) | called by muse, mutect2, varscan2
- BTD | c.-402T>C | 5'UTR (SNP) | VAF 80/176 reads (45%) | called by muse, mutect2, varscan2
- CADM3 | c.*1539G>A | 3'UTR (SNP) | VAF 130/389 reads (33%) | catalogued as rs1254399901; called by muse, mutect2, varscan2
- CCNT2 | c.*3266A>G | 3'UTR (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- CENPP | c.565-10990T>C | Intron (SNP) | VAF 98/329 reads (30%) | called by muse, mutect2, varscan2
- CISH | c.*15C>T | 3'UTR (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- CLASP2 | c.715+4326G>A | Intron (SNP) | VAF 33/69 reads (48%) | called by muse, mutect2, varscan2
- CLVS2 | c.*337G>A | 3'UTR (SNP) | VAF 34/79 reads (43%) | called by muse, varscan2
- DFFA | c.*4843C>T | 3'UTR (SNP) | VAF 14/39 reads (36%) | catalogued as rs1283051716; called by muse, mutect2, varscan2
- DMKN | c.1039-712A>G | Intron (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2, varscan2
- DUSP22 | c.-393C>T | 5'UTR (SNP) | VAF 18/63 reads (29%) | called by muse, mutect2, varscan2
- FAM120A | c.1734+636A>G | Intron (SNP) | VAF 33/112 reads (29%) | called by muse, mutect2, varscan2
- FOXE1 | c.*72G>A | 3'UTR (SNP) | VAF 64/260 reads (25%) | called by muse, mutect2, varscan2
- GABRB3 | c.*427T>C | 3'UTR (SNP) | VAF 32/62 reads (52%) | called by muse, mutect2, varscan2
- GCLC | chr6:53544699 C>T | 5'Flank (SNP) | VAF 18/36 reads (50%) | catalogued as COSV99988821; called by muse, mutect2, varscan2
- GLIPR1L2 | c.670+228G>A | Intron (SNP) | VAF 26/52 reads (50%) | called by muse, mutect2, varscan2
- GLRB | c.-4del | 5'UTR (DEL) | VAF 41/120 reads (34%) | called by mutect2, pindel, varscan2
- GNAT3 | c.-57G>A | 5'UTR (SNP) | VAF 98/207 reads (47%) | called by muse, mutect2, varscan2
- GTPBP2 | c.1632+43G>A | Intron (SNP) | VAF 57/112 reads (51%) | called by muse, mutect2, varscan2
- H2AC17 | c.*28C>G | 3'UTR (SNP) | VAF 106/202 reads (52%) | called by muse, mutect2, varscan2
- HS3ST3B1 | c.*1842G>C | 3'UTR (SNP) | VAF 30/86 reads (35%) | called by muse, mutect2
- IFT172 | c.183+91G>A | Intron (SNP) | VAF 8/25 reads (32%) | catalogued as COSV53129463; called by muse, mutect2
- IFT46 | c.-35-146G>A | Intron (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- IKZF2 | c.*1125A>T | 3'UTR (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- INTS14 | c.*79C>T | 3'UTR (SNP) | VAF 18/152 reads (12%) | called by muse, mutect2, varscan2
- KMT2A | c.432+11247C>T | Intron (SNP) | VAF 15/36 reads (42%) | catalogued as rs938605805; called by muse, mutect2, varscan2
- L3HYPDH | c.940-1381C>T | Intron (SNP) | VAF 154/178 reads (87%) | catalogued as rs1317319074; called by muse, mutect2, varscan2
- LCOR | chr10:96962662 T>G | 3'Flank (SNP) | VAF 37/91 reads (41%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851380 T>C | 5'Flank (SNP) | VAF 58/122 reads (48%) | catalogued as rs1478196210; called by muse, mutect2, varscan2
- MPDZ | c.4003+15del | Intron (DEL) | VAF 160/257 reads (62%) | called by mutect2, varscan2
- NBPF22P | n.1324C>A | RNA (SNP) | VAF 62/167 reads (37%) | called by muse, varscan2
- NBPF22P | n.1325C>G | RNA (SNP) | VAF 62/168 reads (37%) | called by muse, varscan2
- NDUFS7 | c.545-402C>A | Intron (SNP) | VAF 40/101 reads (40%) | catalogued as COSV52039177; called by muse, mutect2, varscan2
- NLGN1 | c.*2017T>G | 3'UTR (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- PHACTR3 | c.*568T>G | 3'UTR (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- RPAIN | c.630+166A>C | Intron (SNP) | VAF 3/8 reads (38%) | called by muse, mutect2
- SCD5 | c.569+20310C>T | Intron (SNP) | VAF 10/27 reads (37%) | catalogued as rs564630776; called by muse, mutect2, varscan2
- SLC1A3 | c.*2053A>T | 3'UTR (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- SLC8A1 | chr2:40112290 C>T | 3'Flank (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- SLK | c.-117G>A | 5'UTR (SNP) | VAF 20/62 reads (32%) | called by muse, varscan2
- SMCO3 | c.*954C>T | 3'UTR (SNP) | VAF 47/113 reads (42%) | called by muse, mutect2, varscan2
- SP3 | c.*3037C>T | 3'UTR (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- SUV39H2 | c.*482G>A | 3'UTR (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- SV2B | c.*4445C>T | 3'UTR (SNP) | VAF 65/156 reads (42%) | catalogued as rs561600380; called by muse, mutect2, varscan2
- TESPA1 | c.*104G>A | 3'UTR (SNP) | VAF 26/68 reads (38%) | called by muse, mutect2, varscan2
- TEX261 | c.*2375C>G | 3'UTR (SNP) | VAF 33/69 reads (48%) | catalogued as rs1364113464; called by muse, mutect2, varscan2
- TMX2 | c.*422T>C | 3'UTR (SNP) | VAF 122/249 reads (49%) | catalogued as rs965472323; called by muse, mutect2, varscan2
- TXNRD2 | c.949+129C>T | Intron (SNP) | VAF 24/42 reads (57%) | called by muse, mutect2, varscan2
- ZNF717 | c.*493del | 3'UTR (DEL) | VAF 3/26 reads (12%) | called by muse*, pindel
- ZNF93 | c.*38C>T | 3'UTR (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
